Gene-level copy-number profile of tumor specimen TCGA-A7-A4SD-01A from TCGA case TCGA-A7-A4SD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 52.4 years (19,131 days).
Specimen TCGA-A7-A4SD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.cf272587-883b-4844-a81e-46fca956cc66.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A4SD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6a263f23-b24b-4667-b16b-d6e6dc013fa6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 4,995; copy number 2: 29,861; copy number 3: 12,871; copy number 4: 9,993; copy number 5: 1,357; copy number 6: 364; copy number 7: 92; copy number 8: 145; copy number 9: 64; copy number 10: 12; copy number 11: 2; copy number 12: 21; copy number 23: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A4SD-01A-11D-A25N-01): tumor purity 0.48, ploidy 2.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,201,647–88,700,401, 34 genes: NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,047 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:162,560,227–163,355,764, 16 genes, copy number 5: AL596325.1, UAP1, AL596325.2, DDR2, RN7SL861P, HSD17B7, CCDC190, AL392003.2, AL392003.1, RGS4, RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2.
- chr5:1,173,141–1,445,440, 12 genes, copy number 7 (within-gene range 3–7): CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3.
- chr5:4,012,708–4,440,259, 4 genes, copy number 8: AC025773.1, AC025187.1, LINC02063, AC106799.3.
- chr5:4,866,521–5,140,119, 8 genes, copy number 6: AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2.
- chr5:5,142,138–5,176,214, 1 gene, copy number 6: AC022424.1.
- chr5:14,970,909–16,617,058, 18 genes, copy number 6–8 (within-gene range 3–8): AC016575.2, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622, RETREG1.
- chr5:16,617,225–16,621,276, 1 gene, copy number 6: AC022113.1.
- chr5:33,367,179–35,230,487, 34 genes, copy number 5–12: AC025472.1, AC034231.1, TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1, AC138409.3, AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1.
- chr5:36,035,021–36,072,079, 2 genes, copy number 8: UGT3A2, AC016612.1.
- chr5:41,868,975–41,968,366, 8 genes, copy number 6: AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6.
- chr6:8,341,937–9,294,133, 3 genes, copy number 7 (within-gene range 4–7): AL359378.1, SLC35B3, HULC.
- chr6:9,124,221–14,285,454, 88 genes, copy number 5–7 (broad region; genes not listed).
- chr10:44,712–13,138,308, 223 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr10:131,772,398–132,205,759, 12 genes, copy number 9–23: LINC01164, AL450307.1, AL607033.1, FP565171.1, PPP2R2D, BNIP3, AL162274.2, AL162274.1, AL162274.3, JAKMIP3, AL512622.1, DPYSL4.
- chr11:41,122,907–50,422,316, 239 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–31,748,240, 794 genes, copy number 5–12 (broad region; genes not listed).
- chr12:39,755,025–40,106,089, 1 gene, copy number 9 (within-gene range 4–9): SLC2A13.
- chr12:40,068,243–44,503,596, 62 genes, copy number 5–12 (broad region; genes not listed).
- chr16:77,433,382–78,066,761, 13 genes, copy number 5: AC025284.1, LINC02131, AC092724.1, NUDT7, AC092134.1, AC092134.3, VAT1L, AC092134.2, PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2.
- chr16:78,123,243–78,168,514, 2 genes, copy number 5: AC079414.3, AC009044.1.
- chr19:28,435,388–28,727,680, 1 gene, copy number 5 (within-gene range 4–5): AC005394.2.
- chr19:28,602,379–37,832,160, 322 genes, copy number 5 (broad region; genes not listed).
- chr20:31,404,845–36,088,192, 183 genes, copy number 6–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,995. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
